Gene-level copy-number profile of tumor specimen C3N-01656-01 from CPTAC case C3N-01656, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.9 years (25,181 days).
Specimen C3N-01656-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ce320a5-5433-47a3-a10d-e05440715726.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01656-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/ca8ed3f5-db2b-472d-9b80-8f7dd3fc6540

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 508; copy number 2: 1,318; copy number 3: 7,472; copy number 4: 19,944; copy number 5: 16,620; copy number 6: 12,089; copy number 9: 958.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 958 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,333,900–137,598,379, 39 genes, copy number 9 (within-gene range 6–9): MACROH2A1, AC026691.1, DCANP1, TIFAB, AC022092.1, NEUROG1, AC034206.1, CXCL14, SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1, LECT2, FBXL21P, TGFBI, VTRNA2-1, Vault, SMAD5-AS1, AC009014.4, SMAD5, AC009014.2, AC009014.3, AC009014.1, SMIM32, TRPC7, TRPC7-AS1, TRPC7-AS2, AC063980.1, HSPD1P18, HNRNPA1P13, AC112178.1, AC109439.1, ANKRD49P3, RNA5SP193, SPOCK1.
- chr5:138,285,265–181,342,213, 919 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
